Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H6, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H6-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Final Results

Surgical Pathology

CASE NUMBER:

DIAGNOSIS:

Final

ICD-0-3

1. Lateral margin #1, 1FS: Fibrous tissue and nerve, no tumor seen.
2. Medial margin, 2FS: Fibroadipose tissue, no tumor seen.
3. Paraspinal tumor and deep margin, excision: Neuroendocrine neoplasm consistent with Extra-adrenal pheochromocytoma (paraganglioma); margins negative, (see note).

Paraganglioma NOS 8693/1
Date: Sept 29/13
W 8/29/13

NOTE: Tumor cells demonstrate strong diffuse staining for chromogranin and synaptophysin with rare cells positive for inhibin. Melan A staining is negative. The morphology and immunohistochemical profile are consistent with pheochromocytoma. Based on the clinical history, this is presumably a primary extra-adrenal pheochromocytoma and not a metastatic pheochromocytoma.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: year old male with presumptive pheochromocytoma.

Specimen Taken For Protocol: - Yes.

Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma.

Post-Operative Diagnosis: pheochromocytoma.

Operative Findings: 3 X 3 cm mass from right posterior chest wall.

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Lateral margin right ling (1FS)
2. ROUTINE + 3FR.SLIDES, Medial margin (2FS)
3. TUMOR, Paraspinal (3FS)

INTRAOPERATIVE CONSULTATION:

1FS: "Lateral margin #1, right lung, blue mark lateral"
1FS diagnosis: Nerve tissue, no evidence for paraganglioma.

2FS: "Medial margin"

Requested By:

Do not file in Medical Record

[page 2 of 3]
2FS diagnosis: Fibroadipose tissue, no tumor seen.

3FS: "Paraspinal tumor/deep margin"

3FS diagnosis: Paraganglioma, tumor extends into the inked margin.

The above results were communicated to

GROSS DESCRIPTION: Received fresh are 3 separate specimens labeled with the patient's name, medical record number, and further specified as follows:

1. "Lateral margin #1, right lung, blue mark lateral" consisting of a tan-brown soft tissue fragment with one edge marked in blue measuring 0.5 x 0.4 x 0.3 cm, which is frozen in total as 1FS. Received in _____ is a specimen matching the above description. It consists of a green cassette labeled "1FS", the contents of which are entirely transferred to an orange cassette labeled _____
2. "Medial margin" consisting of a yellow-tan soft tissue fragment measuring 0.5 x 0.3 x 0.2 cm which is frozen in total as 2FS. Received in _____ a specimen matching the above description. It consists of a green cassette labeled "2FS", the contents of which are entirely transferred to an orange cassette labeled _____
3. "Paraspinal tumor/deep margin" consisting of a red-tan soft tissue fragment measuring 5.0 x 4.0 x 1.8 cm with pleural-based nodule measuring 3.0 x 3.0 x 1.5 cm. The specimen is oriented by _____ in the OR and the deep margin is inked black. An incision is made in the pleural surface and approximately 1.2 x 1.2 x 0.1 cm of tumor are procured for _____ by _____. An incision is made on the posterior margin revealing a freely movable pink-tan homogeneous nodule abutting the posterior margin. Approximately 50% of this nodule is procured for _____ in the OR. Representative section including the inked margin is submitted for frozen section. The superior margin is inked in blue, and the medial margin is inked in green. The remaining tissue is returned to formalin and submitted to Pathology for permanent processing. Received in _____ is a specimen matching the above description. It consists of a green cassette labeled _____ the contents of which are entirely transferred to an orange cassette labeled _____ 3FS. Additionally received is a pleural-based soft tissue fragment with green, blue, and black ink as previously mentioned. A representative section of the tumor and its relationship to the medial margin is submitted in cassette labeled _____ #3A. A representative section of the tumor and its relationship to the superior margin is submitted in cassette labeled _____ #3B. A representative section of the nodule and its relationship to the posterior/deep margin is submitted in cassette labeled _____ #3C. The remaining tissue is returned to formalin.

Requested By:

Do not file in Medical Record

[page 3 of 3]
Surgical Pathology

Final Results

Gross Description dictated by

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Requested By:

Do not file in Medical Record

Criteria	W 5/23/13	Yes	No
Death/Synchronicity Noted			

Source: NCI Genomic Data Commons file 36acafb8-8929-4ef4-bcf3-a3cef6671ec9 (TCGA-QR-A6H6.8C0E7971-2F6C-4036-A1BD-EC613D94A234.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).